Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3455, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3455-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Right Kidney Cancer

Source of Specimen(s):

Right kidney, adrenal and porta caval thrombus

Gross Description:

Received in one part.

Source of Tissue: 1. Labeled #1, "right kidney"

Gross Description: Received fresh labeled , right kidney" is a 426 gram kidney with a moderate amount of

attached perinephric fat. The specimen is bivalved to reveal a 13.0 x 5.0 x 3.5 cm red-tan kidney. There is a 7.5 x 5.0 x 3.0 cm orange tumor situated in the upper and middle poles. In addition there is a 3.5 x 3.0 x 2.0 cm orange tumor protruding from the renal vein. Upon sectioning the tumor extends to within 0.1 cm of the soft tissue margin. The renal pelvis is dilated. The uninvolved kidney is red-tan and unremarkable. A 6.5 cm adrenal gland is identified. Sectioning discloses a red-orange cut surface. Representative sections are submitted as follows: 1A- ureter and artery margins, 1B- renal vein margin and adjacent tissue, 1C-1D- tumor and circumferential margin, 1E- tumor and normal kidney, 1F-1G- tumor in renal pelvis, 1H- random kidney section, 1I- adrenal gland

Final Diagnosis:

1. Right kidney and adrenal gland, radical nephrectomy:
- Clear cell adenocarcinoma, 7.5 cm, Fuhrman grade III.
- Tumor grossly extends into the renal vein.
- Extracapsular extension is not seen.
- The vascular and ureteral margin is negative.
- Adrenal gland with no tumor seen.
- pT3b Nx Mx

Source: NCI Genomic Data Commons file 068fb892-89d6-4d1d-ad92-13179e33bfb0 (TCGA-AK-3455.F8CCCB1A-E98F-4BAD-BB7A-0078B919F56E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).